Surgical pathology report (de-identified scan), TCGA case TCGA-UD-AAC6, project TCGA-MESO (Mesothelioma), tissue source site  University of Western Australia, specimen TCGA-UD-AAC6-01A (Primary Tumor).

[page 1 of 2]
Patient Results

Anatomical Pathology results - Performed from

M

Histopathology

At least 1 Final Result

Histopathology

Final

PATIENT : [REDACTED] LAB. NO. :
ADDRESS : [REDACTED] DOCTOR :
SEX : M WARD :
D.O.B. : REQUEST DATE :
DATE RECEIVED :
CONSULTANT :

SPECIMEN:

Pleura.

CLINICAL :

Malignant mesothelioma left pleura.

MACROSCOPIC:

An irregular strip of pleura 130 x 120 x 2mm. The surface is studded by several irregular firm nodules measuring up to 10mm in diameter. Also submitted are three separate strips of fibrous tissue the largest 30 x 10mm and the smallest 20 x 10mm.

BLOCK KEY:

1-6: Largest pleural fragment, 7,8: Sections from smaller pleural fragments.

MICROSCOPIC:

The sections show strips of pleura composed of fibrous connective tissue and adipose tissue. Both tissue components show infiltration by a malignant mesothelioma. Most of the tumour is of epithelioid type, being composed of neoplastic epithelial cells displaying tubulopapillary architecture and forming irregular nodules. The neoplastic cells have large irregular nuclei with fine chromatin, prominent nucleoli and moderate to abundant amounts of eosinophilic cytoplasm with often distinct cellular boundaries. There is moderate nuclear pleomorphism. Apoptotic cells are present and mitotic figures are easily identified.

Focally the neoplasm is less cellular and displays increased amounts of fibrous connective tissue. The constitutive cells in these areas are spindle in shape and constitute the sarcomatoid component. Elsewhere the neoplastic cells are separated by varying amounts of myxoid-appearing stroma.

Interspersed are occasional nodular areas containing birefringent inorganic material in keeping with talc particles. In association are epithelioid histiocytes and occasional multinucleated foreign body-type giant cells. At the periphery of the tumour is a moderately dense chronic inflammatory cell infiltrate consisting predominantly of lymphocytes. There is accompanying lymphoid aggregate formation.

Some of the tissue strips show paucicellular areas composed of dense collagen, most likely representing part of a pleural plaque. A single section shows blood clot containing aggregates of neoplastic mesothelial cells.

The PAS reaction with diastase digestion for mucin is negative. The Alcian blue stain is positive in the areas of myxoid stroma.

Immunohistochemistry:

The epithelioid malignant cells are positive for cytokeratin 5/6, calretinin and WT-1 and show strong peripheral membranous staining for EMA. The sarcomatoid malignant cells are positive for calretinin and negative for CK5/6 and WT-1 and show patchy cytoplasmic and membranous staining for EMA. Staining for BerEP4 and CEA is negative.

CONCLUSION:

Pleura - Malignant mesothelioma, epithelioid (predominantly) and sarcomatoid patterns.

Clinical history of asbestos exposure and pleural thickening is noted in the previous report of left pleural effusion (lab ref).

REGISTRAR:

PATHOLOGIST:

DOCTOR REVIEWING:

DATED:

ELECTRONICALLY VALIDATED

ICD-O-3
Mesothelioma, malignant lymphatic 9653/3
Site: Pleura NOS C38.4 w/1/29/14

Requested by:

Printed from:

Page: 1 of 2

[page 2 of 2]
Patient Results

Anatomical Pathology results - Performed from

M

Electron Microscopy

At least 1 Final Result

Electron Microscopy

Final

PATIENT
ADDRESS

LAB. NO.

SEX
D.O.B.
DOCTOR

WARD
REQUEST DATE
DATE RECEIVED
CONSULTANT

SPECIMEN:

Pleura.

ELECTRON MICROSCOPY:

Specimen unsuitable for ultrastructural analysis. Dense collagenous fibrous stroma only in all representative blocks.

PATHOLOGIST:

NIHAA Discrepancy		✓

Requested by:

End of Report

Printed from:

Page: 2 of 4

Source: NCI Genomic Data Commons file 4c4ee7e4-9ec8-4343-bfb4-05187241021c (TCGA-UD-AAC6.A033FA57-9895-4942-B3D5-0DA6134881AB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).